ALCHEMIST case ALCH-B2TN — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/5849633c-77c3-432f-b0d4-783d9ba55612

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 61.0 years (22,280 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2TN-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2TN-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2TN-TTP1-C-1-0-S2: Section location: Top; Percent tumor cells: 33; Percent tumor nuclei: 48; Percent normal cells: 35; Percent necrosis: 1; Percent stromal cells: 31; Percent lymphocyte infiltration: 13; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
